Somatic mutation profile of tumor specimen TCGA-WE-A8ZN-06A (aliquot TCGA-WE-A8ZN-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.3 years (22,034 days).
Specimen TCGA-WE-A8ZN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a849d55-9ff9-43bc-b257-c7c5b2310f81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZN-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZN-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d1ad753-11e1-4f32-87ce-739c665eb5c8

The open-access MAF lists 204 somatic variants for this specimen: 132 protein-altering or splice-affecting, 68 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 68, Nonsense Mutation 6, Splice Region 3, Splice Site 3, Intron 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO9A | c.3899C>T p.P1300L | Missense Mutation (SNP) | VAF 56/121 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100612953; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 68/133 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100044898; called by muse, mutect2, varscan2
- ADAMDEC1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976542769, COSV99835917; called by muse, mutect2, varscan2
- ADGRL3 | c.2993G>A p.G998E (on ENST00000506720 / NM_001322402.2; = p.G930E on NM_015236.6) | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546938; called by muse, mutect2, varscan2
- AMER3 | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775957307, COSV100365903, COSV58468421; called by muse, mutect2, varscan2
- AMER3 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as rs1488541723, COSV100366216; called by muse, mutect2, varscan2
- ANK1 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99224537; called by muse, mutect2, varscan2
- ANP32A | c.648T>G p.D216E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV99143003; called by muse, mutect2, varscan2
- AOX1 | c.1598T>C p.I533T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101021834; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100022862; called by muse, mutect2, varscan2
- BCR | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs765208555, COSV59937173; called by muse, mutect2, varscan2
- C3orf20 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs745495398, COSV53782810; called by muse, mutect2
- CAB39L | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1295846922, COSV100759528; called by muse, mutect2, varscan2
- CABP4 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs374363909, COSV57800416; called by muse, mutect2, varscan2
- CACNA1H | c.6986C>T p.P2329L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1433357008, COSV52356287; called by muse, mutect2
- CASR | c.1732C>T p.L578F (on ENST00000490131; = p.L655F on NM_000388.4) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as CD165758, COSV56138436; called by muse, mutect2, varscan2
- CDC42BPA | c.4798C>T p.R1600W (on ENST00000334218 / NM_001366019.2; = p.R1587W on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs373302295; called by muse, mutect2, varscan2
- CELSR2 | c.3773C>T p.S1258F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs766115094, COSV99603364; called by muse, mutect2, varscan2
- CFAP52 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV100234931; called by muse, mutect2, varscan2
- CHRND | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs142928493; called by muse, mutect2, varscan2
- CLIP1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211422, COSV56802942; called by muse, mutect2, varscan2
- CNTN5 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776989902, COSV99674682; called by muse, mutect2, varscan2
- CNTN5 | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99672377, COSV99674766; called by muse, mutect2, varscan2
- CNTN6 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV63162793; called by muse, mutect2, varscan2
- COL12A1 | c.6584C>T p.P2195L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1378279745, COSV100485625; called by muse, mutect2, varscan2
- CPNE4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV70196930, COSV70197493; called by muse, mutect2, varscan2
- CRYBG3 | c.6376C>T p.L2126F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476762; called by muse, mutect2, varscan2
- CTNNA2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV63548813; called by muse, mutect2, varscan2
- CYP4F2 | c.648G>A p.E216= | Splice Region (SNP) | VAF 32/142 reads (23%) | catalogued as COSV50000519; called by muse, mutect2, varscan2
- DEUP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99976900; called by muse, mutect2, varscan2
- DHX9 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100841307; called by muse, mutect2, varscan2
- DSCAM | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as rs766747740, COSV68037397; called by muse, mutect2, varscan2
- DSG2 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV99852954; called by muse, mutect2, varscan2
- EPN3 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.265); catalogued as COSV99276794; called by muse, mutect2, varscan2
- ESRRG | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs149827805; called by muse, mutect2, varscan2
- EYA4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.022); catalogued as rs537561870, COSV62053009; called by muse, mutect2, varscan2
- FAM135B | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99421089; called by muse, mutect2, varscan2
- FBLN1 | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99410252; called by muse, mutect2, varscan2
- FDXACB1 | c.720T>G p.H240Q | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99499625; called by muse, mutect2, varscan2
- FOSB | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.927); catalogued as rs1361311549, COSV100798719; called by muse, mutect2, varscan2
- G6PC | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs774311350, COSV99520705; called by muse, mutect2, varscan2
- GHR | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757458674, COSV100050203; called by muse, mutect2, varscan2
- HECTD2 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99978336; called by muse, mutect2, varscan2
- HELZ | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV100698594; called by muse, mutect2, varscan2
- HEPHL1 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100243718; called by muse, mutect2, varscan2
- HK2 | c.956T>A p.L319H | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308793; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647041; called by muse, mutect2, varscan2
- IGHMBP2 | c.1858C>T p.H620Y | Missense Mutation (SNP) | VAF 61/542 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1039091263, COSV99661937; called by muse, mutect2, varscan2
- IQGAP2 | c.2841A>T p.I947= | Splice Region (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99166856; called by muse, mutect2, varscan2
- ITGAM | c.1993C>T p.R665W (on ENST00000648685 / NM_001145808.2; = p.R664W on NM_000632.4) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372150584; called by muse, mutect2, varscan2
- IVNS1ABP | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.772); catalogued as COSV100832698; called by muse, mutect2, varscan2
- KALRN | c.8027G>A p.W2676* (on ENST00000360013 / NM_001024660.4; = p.W979* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV99361490; called by muse, mutect2, varscan2
- KALRN | c.8028G>A p.W2676* (on ENST00000360013 / NM_001024660.4; = p.W979* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99361496; called by muse, mutect2, varscan2
- KARS1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs768271183, COSV100093895; called by muse, mutect2, varscan2
- KDM4A | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100969414; called by muse, mutect2, varscan2
- LAMB2 | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs777651813, COSV59730778; called by muse, mutect2, varscan2
- MAGEA4 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52342357; called by muse, mutect2, varscan2
- MAP3K19 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs867032344, COSV59642249; called by muse, mutect2, varscan2
- ME3 | c.1132-1G>A p.X378_splice | Splice Site (SNP) | VAF 17/124 reads (14%) | catalogued as COSV100660901; called by muse, mutect2, varscan2
- MRGPRX2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV61674004; called by muse, mutect2, varscan2
- MS4A6E | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.664); catalogued as COSV100279118; called by muse, mutect2, varscan2
- MSH3 | c.3179C>T p.T1060I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV99432808; called by muse, mutect2, varscan2
- MSLN | c.1436G>A p.R479K (on ENST00000382862 / NM_013404.4; = p.R471K on NM_005823.6) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1289786747, COSV99558059; called by muse, mutect2, varscan2
- MTUS1 | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100029221; called by muse, mutect2, varscan2
- MYCT1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as COSV65891853; called by muse, mutect2, varscan2
- MYH1 | c.4380G>A p.W1460* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs1203438599, COSV56850091; called by muse, mutect2, varscan2
- MYH2 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1219331596, COSV55440054; called by muse, mutect2, varscan2
- MYO15A | c.5204G>A p.R1735Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as rs373656823; called by muse, varscan2
- MYO1A | c.744+1G>T p.X248_splice | Splice Site (SNP) | VAF 21/89 reads (24%) | catalogued as rs771181433, COSV100270749; called by muse, mutect2, varscan2
- NBEAL1 | c.5082G>A p.M1694I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV71375397; called by muse, mutect2
- NBEAL1 | c.7570G>A p.G2524S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101355430; called by muse, mutect2, varscan2
- NRAP | c.3440C>T p.S1147F (on ENST00000359988 / NM_001322945.2; = p.S1112F on NM_006175.4) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.24); catalogued as COSV100748351; called by muse, mutect2, varscan2
- OR4C46 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.052); catalogued as rs908497281, COSV60219824; called by muse, mutect2, varscan2
- OR52N2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs779841070, COSV57677546; called by muse, mutect2, varscan2
- OR5M10 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as rs770881915, COSV101595870, COSV73242389; called by muse, mutect2, varscan2
- OR5P3 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100103063; called by muse, mutect2, varscan2
- PBRM1 | c.3454C>T p.H1152Y (on ENST00000296302 / NM_001366071.2; = p.H1127Y on NM_018313.5) | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99967941; called by muse, mutect2, varscan2
- PCDHA4 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV63539763; called by muse, mutect2, varscan2
- PCNT | c.8956G>T p.A2986S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs201877661, COSV100855208; called by muse, mutect2, varscan2
- PFKFB4 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | PolyPhen benign (0.019); catalogued as COSV99219455; called by muse, mutect2, varscan2
- PHC3 | c.272C>T p.S91F (on ENST00000494943 / NM_001308116.2; = p.S103F on NM_024947.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV101518912; called by muse, mutect2, varscan2
- PKHD1L1 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV101005748; called by muse, mutect2, varscan2
- PLXNC1 | c.3380_3381insCA p.R1127Sfs*36 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as COSV99312674; called by mutect2, pindel, varscan2
- POTEH | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV100624828, COSV58879522; called by muse, varscan2
- PPP4R4 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1312956891, COSV58560003; called by muse, varscan2
- PPP4R4 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100428422, COSV100428501; called by muse, mutect2, varscan2
- PRSS1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61194406; called by muse, varscan2
- PRUNE2 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100944333; called by muse, mutect2, varscan2
- PSD4 | c.2947G>A p.V983M | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1172800615, COSV99830931; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- RASAL1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as rs1401246615, COSV55654530; called by muse, mutect2, varscan2
- RBMS1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs1342378366, COSV100816763; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RIC8A | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs371064171, COSV100254745; called by muse, mutect2, varscan2
- RP1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs1246897709, COSV55127977; called by muse, mutect2, varscan2
- RPP38 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100975496; called by muse, mutect2, varscan2
- RSRC1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99905691; called by muse, mutect2, varscan2
- RYR3 | c.3019A>C p.I1007L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.455); catalogued as COSV101212251; called by muse, mutect2
- SCN11A | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56566178; called by muse, mutect2
- SERPINB11 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as rs751508430, COSV101236180; called by muse, mutect2, varscan2
- SH3RF2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV100767663; called by muse, mutect2, varscan2
- SLC15A2 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55196319; called by muse, mutect2, varscan2
- SLC27A4 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100056571; called by muse, mutect2, varscan2
- SLC7A7 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99591585; called by muse, mutect2, varscan2
- STMN3 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV100899856, COSV64246626; called by muse, mutect2, varscan2
- SULT1A2 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1485601343, COSV100187082; called by muse, mutect2, varscan2
- SYTL2 | c.1351A>C p.T451P | Missense Mutation (SNP) | VAF 217/287 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100313853; called by muse, mutect2, varscan2
- TAGAP | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs139378811; called by muse, mutect2, varscan2
- TARBP1 | c.2612T>C p.V871A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV50189052; called by muse, mutect2, varscan2
- TERB2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546539; called by muse, mutect2, varscan2
- TEX15 | c.5899G>A p.A1967T (on ENST00000256246; = p.A2350T on NM_001350162.2) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV56350714, COSV99821005; called by muse, mutect2, varscan2
- TOE1 | c.492G>A p.K164= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1197716987, COSV100517178; called by muse, mutect2, varscan2
- TOE1 | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100517179; called by muse, mutect2, varscan2
- TOGARAM2 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs757373675, COSV101090968; called by muse, mutect2, varscan2
- TRIM24 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV100630777; called by muse, mutect2, varscan2
- TRIM38 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100837554; called by muse, mutect2, varscan2
- TSPEAR | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1277378753, COSV59952918; called by muse, mutect2, varscan2
- TTN | c.78905G>A p.G26302E (on ENST00000591111; = p.G18878E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | PolyPhen probably damaging (1); catalogued as rs763624309, COSV100601329; called by muse, mutect2, varscan2
- TTN | c.55987A>C p.T18663P (on ENST00000591111; = p.T11239P on NM_003319.4) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | PolyPhen possibly damaging (0.649); catalogued as COSV100601330; called by muse, mutect2, varscan2
- TULP4 | c.3353G>A p.R1118Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); catalogued as rs367675484, COSV100893317; called by muse, mutect2, varscan2
- UBR4 | c.12113C>T p.P4038L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs1327016045, COSV100920623; called by muse, mutect2, varscan2
- UCP1 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53767682, COSV99530174; called by muse, mutect2, varscan2
- UNC13C | c.4810G>A p.D1604N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs267604264, COSV99513915; called by muse, mutect2, varscan2
- WDR24 | c.1661G>A p.R554Q (on ENST00000248142; = p.R424Q on NM_032259.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs749743422, COSV50201894; called by muse, mutect2, varscan2
- ZBBX | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56790820; called by muse, mutect2, varscan2
- ZBBX | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs770804757, COSV56786655; called by muse, mutect2, varscan2
- ZIM3 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.546); catalogued as COSV54145414, COSV99517869; called by muse, mutect2, varscan2
- RIOK2 | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2
- USP35 | c.1688del p.S563* | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- ABCC4 | c.1056C>T p.F352= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as rs764661404, COSV65309490; called by muse, mutect2, varscan2
- ABCC9 | c.3144C>T p.F1048= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV53966246; called by muse, mutect2, varscan2
- ACTC1 | c.309C>T p.H103= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs769303249, CM1412326, COSV51762111; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS18 | c.255G>A p.R85= | Silent (SNP) | VAF 71/351 reads (20%) | catalogued as COSV51398255; called by muse, mutect2, varscan2
- ADAR | c.3000C>T p.L1000= | Silent (SNP) | VAF 55/242 reads (23%) | catalogued as COSV52718325; called by muse, mutect2, varscan2
- AFMID | c.573C>T p.F191= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as COSV59977535; called by muse, mutect2, varscan2
- AIP | c.177C>T p.P59= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs1301661778, COSV99653598; called by muse, mutect2, varscan2
- C11orf16 | c.1359G>A p.R453= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV100214884; called by muse, mutect2, varscan2
- CD93 | c.1626C>G p.G542= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99849017, COSV99849801; called by muse, mutect2, varscan2
- CFAP54 | c.6345C>T p.I2115= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100733044; called by muse, mutect2, varscan2
- CPXM2 | c.564A>G p.R188= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99581460; called by muse, mutect2, varscan2
- DCST2 | c.639C>T p.F213= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs562006776, COSV55052897; called by muse, mutect2, varscan2
- DKK4 | c.411G>A p.R137= | Silent (SNP) | VAF 63/326 reads (19%) | catalogued as COSV99612655; called by muse, mutect2, varscan2
- DLG4 | c.2022C>T p.F674= (on ENST00000399506 / NM_001321075.3; = p.F717= on NM_001365.4) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs375597341, COSV100263508; called by muse, mutect2, varscan2
- DMRT3 | c.807C>T p.L269= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs767728089, COSV99505717; called by muse, mutect2, varscan2
- DNAJB5 | c.363C>T p.F121= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs1471001558, COSV100257781; called by muse, mutect2, varscan2
- DRC1 | c.1758G>A p.L586= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs1460141815, COSV99716967; called by muse, mutect2, varscan2
- EMX1 | c.843G>A p.G281= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs746513092, COSV99252432; called by muse, mutect2, varscan2
- EPAS1 | c.2475G>T p.R825= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as COSV99763032; called by muse, mutect2, varscan2
- FBXL18 | c.1233G>A p.R411= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1204532663, COSV101212034; called by muse, mutect2, varscan2
- GDE1 | c.990C>T p.H330= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99572277; called by muse, mutect2, varscan2
- GDF5 | c.450G>A p.R150= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100976763; called by muse, mutect2, varscan2
- GPR35 | c.681G>C p.V227= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs767578418, COSV100166387; called by muse, mutect2, varscan2
- IGKV3-7 | c.91C>T p.L31= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- IQCG | c.345C>T p.I115= | Silent (SNP) | VAF 93/344 reads (27%) | catalogued as rs1396234194, COSV99502196; called by muse, mutect2, varscan2
- KRTAP5-9 | c.207G>A p.K69= | Silent (SNP) | VAF 45/385 reads (12%) | catalogued as COSV101603618; called by muse, mutect2, varscan2
- LARP1 | c.2703G>A p.R901= (on ENST00000518297 / NM_033551.3; = p.R824= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100303586; called by muse, mutect2, varscan2
- LIPK | c.753C>T p.F251= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV101344961; called by muse, mutect2, varscan2
- MCM3 | c.1746C>T p.I582= (on ENST00000229854 / NM_001366374.2; = p.I572= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100008670; called by muse, mutect2, varscan2
- MED25 | c.1092A>G p.A364= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100457187; called by muse, mutect2, varscan2
- MEI1 | c.1617C>T p.T539= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1277876253, COSV100299745; called by muse, mutect2, varscan2
- MSLN | c.858G>A p.R286= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV53499584; called by muse, mutect2, varscan2
- MUC16 | c.4806G>A p.E1602= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV101198939, COSV67491493; called by muse, mutect2, varscan2
- MYH14 | c.5433C>T p.I1811= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99222163; called by muse, mutect2, varscan2
- MYH9 | c.912C>T p.S304= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV99338232; called by muse, mutect2, varscan2
- MYLK2 | c.420G>A p.R140= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1555789909, COSV101044719; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPC1L1 | c.2844C>T p.I948= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99203598; called by muse, mutect2, varscan2
- NPFFR1 | c.300C>T p.T100= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs749138174, COSV99524715; called by muse, mutect2, varscan2
- NUAK1 | c.1914C>T p.S638= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV99776789; called by muse, mutect2, varscan2
- OR1J4 | c.339C>T p.F113= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as rs768040110, COSV61589566; called by muse, mutect2, varscan2
- OR7C2 | c.606G>A p.V202= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV99934461; called by muse, mutect2, varscan2
- PCSK1 | c.258C>T p.I86= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV60735428; called by muse, mutect2, varscan2
- PIK3R5 | c.2343G>A p.V781= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99353057; called by muse, mutect2, varscan2
- PLXNB1 | c.594C>T p.F198= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs111761006, COSV99602530; called by muse, varscan2
- PNLDC1 | c.1203C>T p.I401= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99277241; called by muse, mutect2, varscan2
- PRDM14 | c.1158G>A p.G386= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99399986; called by muse, mutect2, varscan2
- PROKR1 | c.936C>T p.T312= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs763997438, COSV58136522; called by muse, mutect2, varscan2
- PTGER3 | c.399C>T p.F133= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs765893089, COSV100138518; called by muse, varscan2
- RAET1G | c.228C>T p.P76= | Silent (SNP) | VAF 68/313 reads (22%) | catalogued as COSV100951647; called by muse, mutect2, varscan2
- RAI2 | c.624C>T p.G208= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100518217; called by muse, mutect2, varscan2
- RNASEH2A | c.804C>T p.I268= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99677270; called by muse, mutect2, varscan2
- SCGB1C1 | c.22C>T p.L8= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1265368299, COSV100285209; called by muse, mutect2, varscan2
- SCRN3 | c.15C>T p.S5= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs1358309254, COSV99767157; called by muse, mutect2, varscan2
- SEC22A | c.600T>A p.L200= | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as COSV100006882; called by muse, mutect2, varscan2
- SEMA4A | c.2175G>A p.G725= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100740504; called by muse, mutect2, varscan2
- SGSM1 | c.1998G>A p.A666= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs368461788; called by muse, mutect2, varscan2
- SLC7A13 | c.891C>T p.T297= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as rs572819592, COSV99878654; called by muse, mutect2, varscan2
- SLC7A14 | c.1821G>A p.L607= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV51589709; called by muse, mutect2, varscan2
- SLCO6A1 | c.1254C>T p.P418= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV65806181; called by muse, mutect2, varscan2
- SMARCA2 | c.471C>T p.I157= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV100570556; called by muse, mutect2, varscan2
- STAT3 | c.39G>A p.R13= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99232587; called by muse, varscan2
- SUSD1 | c.1155C>T p.I385= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1188103507, COSV62585616; called by muse, mutect2, varscan2
- TACR2 | c.81C>T p.S27= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100964789; called by muse, mutect2, varscan2
- TMEM63C | c.834C>T p.F278= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100029290; called by muse, mutect2, varscan2
- UBN1 | c.2520C>T p.S840= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV52173996; called by muse, mutect2, varscan2
- UBXN6 | c.675G>A p.K225= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100010984; called by muse, mutect2, varscan2
- VPS18 | c.993C>T p.T331= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1161523581, COSV99592380; called by muse, mutect2, varscan2
- ZIM3 | c.252G>A p.G84= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV54144157, COSV99517872; called by muse, mutect2, varscan2
- FBXL13 | c.496-5534G>A | Intron (SNP) | VAF 29/110 reads (26%) | catalogued as rs1301875694, COSV57544205; called by muse, mutect2, varscan2
- SNORD115-13 | n.66G>A | RNA (SNP) | VAF 123/513 reads (24%) | catalogued as rs746465371; called by muse, mutect2, varscan2
- TTN | c.10303+2297G>A | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as rs1408667459, COSV59903105; called by muse, mutect2, varscan2
- ZDHHC23 | c.1041-548G>A | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs1215225665, COSV100362075; called by muse, mutect2, varscan2
